Somatic mutation profile of tumor specimen 0DCER6 from CCDI case PBBMLN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 4.1 years (1,494 days).
Specimen 0DCER6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 440bfab5-799b-4a0f-8a45-bd71e154fd8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCEQZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14dae3a4-c92b-44be-a77b-2b09c6eb1e7f

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Intron 2, 5'UTR 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LYST | c.3891G>T p.L1297F | Missense Mutation (SNP) | VAF 102/684 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1328642726, COSV101088642; called by muse, mutect2, varscan2
- MTF1 | c.1414G>C p.V472L | Missense Mutation (SNP) | VAF 126/368 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs1296443975; called by muse, mutect2, varscan2
- PCNX2 | c.3364C>G p.R1122G | Missense Mutation (SNP) | VAF 317/618 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV50837690; called by muse, mutect2, varscan2
- RAD23A | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 151/725 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as rs754368275; called by muse, mutect2, varscan2
- RTEL1 | c.3277G>A p.D1093N | Missense Mutation (SNP) | VAF 129/302 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as rs767674666, COSV53927740; called by muse, mutect2, varscan2
- CCM2 | c.504T>G p.S168R | Missense Mutation (SNP) | VAF 207/539 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- DCHS1 | c.4382C>T p.S1461L | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K5 | c.2306A>C p.K769T | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLRP2 | c.768C>A p.C256* | Nonsense Mutation (SNP) | VAF 125/599 reads (21%) | called by muse, mutect2, varscan2
- PKD1L1 | c.7584G>T p.L2528= | Splice Region (SNP) | VAF 239/553 reads (43%) | called by muse, mutect2, varscan2
- ZNF20 | c.740G>T p.R247I | Missense Mutation (SNP) | VAF 126/615 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM5 | c.984G>A p.V328= | Silent (SNP) | VAF 133/351 reads (38%) | catalogued as rs1267789191; called by muse, mutect2, varscan2
- EFNB1 | c.211C>A p.R71= | Silent (SNP) | VAF 164/191 reads (86%) | catalogued as COSV52661024, COSV52662951; called by muse, mutect2, varscan2
- FSIP2 | c.7956T>C p.P2652= | Silent (SNP) | VAF 267/1030 reads (26%) | called by muse, mutect2, varscan2
- MUC16 | c.19722G>A p.P6574= | Silent (SNP) | VAF 62/344 reads (18%) | catalogued as COSV67502724; called by muse, mutect2, varscan2
- PDGFRL | c.957G>A p.T319= | Silent (SNP) | VAF 166/723 reads (23%) | catalogued as rs201682806, COSV50605726; called by muse, mutect2, varscan2
- POTEB3 | c.864G>T p.V288= | Silent (SNP) | VAF 183/1229 reads (15%) | called by muse, mutect2, varscan2
- CEP290 | c.6136-49C>A | Intron (SNP) | VAF 71/205 reads (35%) | called by muse, mutect2, varscan2
- CHRD | c.-80C>A | 5'UTR (SNP) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- YARS1 | c.1141-63G>A | Intron (SNP) | VAF 79/136 reads (58%) | called by muse, mutect2, varscan2
